Somatic mutation profile of tumor specimen TCGA-D7-6526-01A (aliquot TCGA-D7-6526-01A-11D-1800-08) from TCGA case TCGA-D7-6526, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.0 years (24,477 days).
Specimen TCGA-D7-6526-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8581e1c4-aaf8-449c-a35a-33dae46e1f85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6526-10A (Blood Derived Normal), aliquot TCGA-D7-6526-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a60e9da-8b3a-4854-b51c-64e0b00066ad

The open-access MAF lists 225 somatic variants for this specimen: 158 protein-altering or splice-affecting, 57 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 144, Silent 57, RNA 5, In Frame Del 4, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, 5'Flank 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs528234968, COSV57295994; called by muse, mutect2, varscan2
- ADGRG4 | c.1750T>G p.L584V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV54963426; called by muse, mutect2, varscan2
- ANKRD30A | c.3433G>A p.E1145K (on ENST00000611781; = p.E1089K on NM_052997.2) | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV64617128; called by muse, mutect2, varscan2
- AP002512.3 | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56565679; called by muse, mutect2, varscan2
- ASXL3 | c.3292A>C p.T1098P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52474752; called by muse, mutect2, varscan2
- ATP4B | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs370798858; called by muse, mutect2, varscan2
- B4GALT4 | c.1015G>C p.D339H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV63296321; called by muse, mutect2, varscan2
- BBS7 | c.1629T>G p.F543L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV52658591; called by muse, mutect2, varscan2
- C14orf39 | c.1585G>T p.G529* | Nonsense Mutation (SNP) | VAF 52/156 reads (33%) | catalogued as COSV58784080; called by muse, mutect2
- CA9 | c.437A>T p.D146V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as COSV65676323; called by muse, mutect2
- CACNA1E | c.6083G>A p.R2028H (on ENST00000367573 / NM_001205293.3; = p.R1985H on NM_000721.4) | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as rs1014152863, COSV62410350; called by muse, mutect2, varscan2
- CBLN2 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54052485; called by muse, mutect2, varscan2
- CENPF | c.4136T>G p.V1379G | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.095); catalogued as COSV65277772; called by muse, mutect2, varscan2
- CFAP61 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV55641349; called by muse, mutect2, varscan2
- CMTR2 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV57604544; called by muse, mutect2, varscan2
- CNGB1 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs574295098, COSV51901177; called by muse, mutect2, varscan2
- CNTN4 | c.1443C>A p.N481K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61878228; called by muse, mutect2, varscan2
- COG7 | c.1412T>G p.I471R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56152152; called by muse, mutect2, varscan2
- CSMD3 | c.10622T>C p.L3541P (on ENST00000297405 / NM_001363185.1; = p.L3372P on NM_052900.3) | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52270735; called by muse, mutect2, varscan2
- CSMD3 | c.6838G>A p.E2280K (on ENST00000297405 / NM_001363185.1; = p.E2176K on NM_052900.3) | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as rs1416124406, COSV52270769; called by muse, mutect2, varscan2
- CTNNA3 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs1032740164, COSV65585635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA3 | c.1052G>C p.G351A | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65562416, COSV65609223; called by muse, varscan2
- DCX | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV57573604; called by muse, mutect2
- DLD | c.258T>G p.I86M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.626); catalogued as COSV52739149; called by muse, mutect2, varscan2
- DNAH3 | c.3324A>T p.E1108D | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV54540987; called by muse, mutect2, varscan2
- DPYD | c.1757T>G p.V586G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64609457; called by muse, mutect2, varscan2
- DYSF | c.2701T>A p.Y901N | Missense Mutation (SNP) | VAF 107/347 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs774078137, COSV50517130; called by muse, mutect2, varscan2
- EGFLAM | c.2535C>A p.Y845* (on ENST00000354891 / NM_001205301.2; = p.Y837* on NM_152403.4) | Nonsense Mutation (SNP) | VAF 29/237 reads (12%) | catalogued as COSV59312489; called by muse, mutect2, varscan2
- ENC1 | c.1614C>A p.N538K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.703); catalogued as COSV56630625; called by muse, mutect2, varscan2
- EPB41L3 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs1009731371, COSV59456726; called by muse, mutect2, varscan2
- EPHA5 | c.1495A>G p.I499V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV56663356; called by muse, mutect2, varscan2
- ETF1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62127909; called by muse, mutect2, varscan2
- FAM71B | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs749376814, COSV57227450; called by muse, mutect2, varscan2
- FBLN1 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV53052113; called by muse, mutect2, varscan2
- FGF14 | c.439del p.E147Nfs*9 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as COSV101084423, COSV65941304; called by mutect2, pindel
- FILIP1 | c.320A>C p.K107T | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV52737346; called by muse, mutect2, varscan2
- FKBP2 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV58588351, COSV58588548; called by muse, mutect2, varscan2
- FLG | c.9803C>A p.A3268E | Missense Mutation (SNP) | VAF 234/708 reads (33%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.978); catalogued as COSV64245916, COSV64251371; called by muse, mutect2, varscan2
- FLG | c.7534A>G p.S2512G | Missense Mutation (SNP) | VAF 64/712 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV64241812, COSV64245918; called by muse, mutect2
- FRYL | c.466T>A p.F156I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51956760; called by muse, mutect2, varscan2
- FSHR | c.438A>T p.K146N | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as rs1295299288, COSV58618791, COSV58620376, COSV58630781; called by muse, mutect2, varscan2
- FTHL17 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV63267569; called by muse, mutect2, varscan2
- GAB4 | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68754759; called by muse, mutect2, varscan2
- GAS2L3 | c.193A>T p.K65* | Nonsense Mutation (SNP) | VAF 22/151 reads (15%) | catalogued as COSV57158529; called by muse, mutect2, varscan2
- GLRA1 | c.572T>C p.M191T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as COSV51021903; called by muse, mutect2, varscan2
- GLRB | c.728G>C p.C243S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52420533; called by muse, mutect2, varscan2
- GNPTAB | c.2884G>A p.D962N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV68449872; called by muse, mutect2, varscan2
- GPATCH4 | c.220T>G p.F74V | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58041107; called by muse, mutect2, varscan2
- GRIA2 | c.1804T>G p.L602V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV52400706; called by muse, mutect2, varscan2
- GRM8 | c.2467A>G p.S823G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as rs1378227870, COSV58822677, COSV58854679; called by muse, mutect2, varscan2
- GUCY2F | c.2306C>T p.P769L | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1375269870, COSV54306485; called by muse, mutect2, varscan2
- IL10 | c.382C>G p.R128G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV65594772, COSV65594856; called by muse, mutect2, varscan2
- IL13RA2 | c.361A>C p.S121R | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54566917; called by muse, mutect2
- IQGAP2 | c.1793G>C p.G598A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV57178833; called by muse, mutect2
- IRS4 | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs759864957, COSV64534855; called by muse, mutect2, varscan2
- ITGB1 | c.2293A>G p.K765E | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56485167; called by muse, mutect2, varscan2
- KCNA2 | c.1364A>C p.K455T | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV60371059; called by muse, mutect2, varscan2
- KCNA2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1386301058, COSV60369330, COSV60370715; called by muse, mutect2, varscan2
- KMT2D | c.3868C>T p.R1290W | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs769946520, COSV56417134; called by muse, mutect2, varscan2
- LAMA1 | c.2741G>A p.C914Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481376594, COSV67541776; called by muse, mutect2, varscan2
- LIN54 | c.1890G>T p.K630N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV61202395; called by muse, mutect2, varscan2
- LNX1 | c.966C>A p.D322E (on ENST00000263925 / NM_001126328.3; = p.D226E on NM_032622.2) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55789977, COSV55792848; called by muse, mutect2, varscan2
- LRP4 | c.5258A>G p.K1753R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.076); catalogued as COSV66137732; called by muse, mutect2, varscan2
- LRRK2 | c.5845T>G p.L1949V | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54164432; called by muse, mutect2, varscan2
- LUM | c.634T>G p.L212V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs749360955, COSV57127364, COSV57129189; called by muse, mutect2, varscan2
- LUZP1 | c.2950G>A p.D984N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.372); catalogued as COSV56504065; called by muse, mutect2, varscan2
- MAGEE1 | c.2338A>G p.S780G | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as COSV63911599; called by muse, mutect2, varscan2
- MAP2 | c.2151C>G p.N717K | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as COSV52302583; called by muse, mutect2, varscan2
- MARCO | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59056979; called by muse, mutect2, varscan2
- MATN2 | c.1089C>A p.D363E | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54716835; called by muse, mutect2
- MDC1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV64526333; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | catalogued as rs1180255648; called by mutect2, pindel
- MED14 | c.4337T>G p.L1446R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59948058; called by muse, mutect2, varscan2
- MLLT10 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 73/311 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as rs369695121; called by muse, mutect2, varscan2
- MROH9 | c.383T>C p.L128P | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.476); catalogued as COSV63012657; called by muse, mutect2, varscan2
- NADK2 | c.1102C>A p.P368T (on ENST00000381937 / NM_001085411.3; = p.P205T on NM_153013.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV56938693; called by muse, mutect2, varscan2
- NAMPT | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.439); catalogued as COSV99748191; called by muse, mutect2
- NDST4 | c.1118A>T p.E373V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV52131064, COSV52136540; called by muse, mutect2, varscan2
- NID1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV51625894; called by muse, mutect2
- NLGN3 | c.1796G>A p.R599Q (on ENST00000358741 / NM_181303.2; = p.R579Q on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV62442759; called by muse, mutect2
- OR2A2 | c.809A>C p.E270A | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV68872260; called by muse, mutect2, varscan2
- OR2B2 | c.1000T>G p.F334V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV57579223; called by muse, mutect2, varscan2
- OR2F2 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.098); catalogued as COSV68833177; called by muse, mutect2, varscan2
- OR4N5 | c.903G>T p.L301F | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs1197632188, COSV61321060; called by muse, mutect2
- OR51I1 | c.620T>G p.F207C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.873); catalogued as COSV66508786; called by muse, mutect2
- OR5T2 | c.649T>C p.F217L | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV57590427; called by muse, mutect2, varscan2
- OR6Y1 | c.896A>C p.N299T | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56930834; called by muse, mutect2, varscan2
- OR8J3 | c.545C>A p.A182E | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV56883170; called by muse, mutect2, varscan2
- ORC4 | c.690T>G p.F230L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.113); catalogued as COSV51576089; called by muse, mutect2, varscan2
- PCDH11X | c.3073G>A p.E1025K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV53492551; called by muse, mutect2, varscan2
- PCDH15 | c.5114A>C p.K1705T (on ENST00000644397 / NM_001354429.2; = p.K1647T on NM_001142771.2) | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.197); catalogued as COSV64720392, COSV64754688; called by muse, mutect2, varscan2
- PCDHGB4 | c.1658G>A p.R553H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs765744557, COSV54003159; called by muse, mutect2, varscan2
- PDZD2 | c.905C>A p.T302N | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV56868090; called by muse, mutect2, varscan2
- PEG3 | c.3823A>G p.S1275G | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.582); catalogued as COSV55629227, COSV55642916; called by muse, mutect2, varscan2
- PGR | c.2476C>G p.L826V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV54807825; called by muse, mutect2, varscan2
- PHLDB1 | c.1424G>A p.R475Q | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.46); catalogued as rs782475070, COSV61876865, COSV61880678; called by muse, mutect2
- PHPT1 | c.238T>C p.S80P | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.664); catalogued as COSV56034457; called by muse, mutect2, varscan2
- PNPLA2 | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs745927123, COSV60744923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA8 | c.1058T>G p.I353S | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV57554086; called by muse, mutect2, varscan2
- PRICKLE3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs976611550, COSV66235301; called by muse, varscan2
- PRKCQ | c.2098G>A p.G700R | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.117); catalogued as rs748100103, COSV54112707; called by muse, mutect2, varscan2
- RAB3GAP1 | c.937_938insAA p.R313Kfs*13 | Frame Shift Ins (INS) | VAF 16/139 reads (12%) | catalogued as COSV99920593; called by mutect2, pindel, varscan2
- RBM19 | c.929T>A p.V310D | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55696488; called by muse, mutect2, varscan2
- RBM4B | c.137C>A p.T46K | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV100026501; called by muse, mutect2, varscan2
- RECQL | c.1364G>T p.R455L | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs778148225, COSV53711142; called by muse, mutect2, varscan2
- RNF165 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV53974920, COSV99492039; called by mutect2, varscan2
- RORA | c.356G>A p.R119Q (on ENST00000335670 / NM_134261.3; = p.R144Q on NM_002943.3) | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55042748; called by muse, mutect2, varscan2
- RP1 | c.3844C>T p.P1282S | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs866399055, COSV55111239; called by muse, mutect2, varscan2
- RTN2 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.186); catalogued as COSV99839184; called by muse, mutect2
- RTN4 | c.3323G>A p.R1108H (on ENST00000337526 / NM_020532.5; = p.R115H on NM_007008.3) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs888288659, COSV58271916; called by muse, mutect2, varscan2
- RYR2 | c.4545C>A p.S1515R | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV63704113; called by muse, varscan2
- SCN3A | c.4528C>T p.R1510C | Missense Mutation (SNP) | VAF 187/331 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs758596091, COSV51806986; called by muse, mutect2, varscan2
- SECISBP2 | c.1262G>A p.R421K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV60529750; called by muse, mutect2, varscan2
- SI | c.1742A>C p.K581T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as COSV100013748, COSV52271290; called by muse, mutect2, varscan2
- SLC16A2 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV52087450; called by muse, mutect2, varscan2
- SLC22A2 | c.323C>A p.A108D | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV65267340; called by muse, mutect2, varscan2
- SLC45A1 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs766677852, COSV57094390; called by muse, mutect2, varscan2
- SMC3 | c.2636G>A p.R879Q | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.491); catalogued as rs797045996, COSV62419803; called by muse, mutect2, varscan2
- SPATA31D1 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV61199442; called by muse, mutect2, varscan2
- SPEF2 | c.726A>C p.E242D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV56795270, COSV56795840; called by muse, mutect2, varscan2
- SPINK4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.904); catalogued as rs140712741, COSV101121887; called by mutect2, varscan2
- STAG1 | c.2000A>G p.D667G | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV99366536; called by muse, mutect2, varscan2
- STAG1 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV52623080, COSV99366539; called by muse, mutect2, varscan2
- SYCP1 | c.1150G>C p.V384L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs529219579, COSV65700042; called by muse, mutect2, varscan2
- SYT2 | c.467T>A p.L156H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66142726; called by muse, mutect2
- TACC2 | c.8552A>G p.K2851R (on ENST00000334433; = p.K929R on NM_006997.4) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53287017; called by muse, mutect2, varscan2
- TAGAP | c.1548C>A p.H516Q | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.437); catalogued as COSV57852760; called by muse, mutect2, varscan2
- TECRL | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs867978042, COSV67085544; called by muse, mutect2, varscan2
- TGM5 | c.406T>G p.F136V | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV55011509; called by muse, mutect2, varscan2
- TMEM74 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs911946149, COSV52463296; called by muse, mutect2, varscan2
- TNS2 | c.2983C>T p.H995Y (on ENST00000314250 / NM_170754.4; = p.H1005Y on NM_015319.2) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56855272; called by muse, mutect2, varscan2
- TRIM72 | c.721T>C p.Y241H | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV57251938; called by muse, mutect2, varscan2
- TRIO | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs368654118; called by muse, mutect2, varscan2
- TTL | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV51975872; called by mutect2, varscan2
- USP49 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51899892; called by muse, mutect2, varscan2
- UTRN | c.8314C>T p.R2772C | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs1362046119, CM142663, COSV62311728; called by muse, mutect2
- VGLL3 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67354038; called by muse, mutect2, varscan2
- VPS39 | c.436C>T p.L146F (on ENST00000348544 / NM_001301138.2; = p.L135F on NM_015289.5) | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.367); catalogued as COSV58792049; called by muse, mutect2, varscan2
- XIRP2 | c.248A>T p.K83M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV54723339; called by muse, mutect2, varscan2
- ZBBX | c.2176T>G p.F726V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56797253; called by muse, mutect2, varscan2
- ZFP91 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV60161053; called by muse, mutect2, varscan2
- ZMAT1 | c.1801A>T p.S601C | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV65659607; called by muse, mutect2, varscan2
- ZNF536 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 162/287 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750913170, COSV62824867; called by muse, mutect2, varscan2
- ZNF549 | c.621A>T p.Q207H (on ENST00000376233 / NM_001199295.2; = p.Q194H on NM_153263.2) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV53727090, COSV53728067; called by muse, mutect2, varscan2
- ZNF568 | c.1136T>C p.L379P | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); catalogued as COSV61742529; called by muse, mutect2, varscan2
- ZNF614 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 139/208 reads (67%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV54547711; called by muse, mutect2, varscan2
- ZNF665 | c.1007C>T p.P336L (on ENST00000600412; = p.P401L on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV67216689; called by muse, mutect2, varscan2
- ZNF669 | c.1319A>G p.H440R | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs758238442, COSV58538890; called by muse, mutect2, varscan2
- ZNF98 | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV100757567, COSV63334161; called by muse, mutect2, varscan2
- COL15A1 | c.2123del p.K708Rfs*44 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- LCE4A | c.72dup p.C25Mfs*30 | Frame Shift Ins (INS) | VAF 26/245 reads (11%) | called by mutect2, pindel, varscan2
- MLLT3 | c.258_263del p.E86_Y88delinsD | In Frame Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- OR2B6 | c.79_82dup p.L28Pfs*85 | Frame Shift Ins (INS) | VAF 16/105 reads (15%) | called by mutect2, pindel, varscan2
- PER2 | c.2336G>A p.R779K | Missense Mutation (SNP) | VAF 2/11 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2
- PRSS22 | c.587_592del p.Q196_K197del | In Frame Del (DEL) | VAF 38/295 reads (13%) | called by mutect2, pindel, varscan2
- RBM34 | c.321_326del p.A108_K109del | In Frame Del (DEL) | VAF 46/164 reads (28%) | called by mutect2, pindel, varscan2
- SPATA7 | c.1729_1731del p.N577del | In Frame Del (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- TP53 | c.1029_1033dup p.N345Sfs*2 | Nonsense Mutation (INS) | VAF 22/36 reads (61%) | called by mutect2, varscan2
- ABCA2 | c.6879C>A p.R2293= (on ENST00000614293; = p.R2263= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV55804762; called by muse, mutect2, varscan2
- AMMECR1 | c.825G>A p.L275= | Silent (SNP) | VAF 72/183 reads (39%) | catalogued as COSV53319475; called by muse, mutect2, varscan2
- ATP8A1 | c.1920C>T p.L640= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs770450885, COSV52527700; called by muse, mutect2, varscan2
- BEND5 | c.1026C>T p.S342= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs149855111, COSV65718233; called by muse, mutect2, varscan2
- BRINP1 | c.231T>A p.R77= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV56309177; called by muse, mutect2, varscan2
- CACNG8 | c.375C>T p.V125= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV54416184; called by muse, mutect2, varscan2
- CBLN4 | c.558A>G p.G186= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV50353868; called by muse, mutect2, varscan2
- CCER1 | c.444C>T p.R148= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV62646982; called by mutect2, varscan2
- CD40LG | c.369G>A p.A123= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as rs148581967, COSV65698903; ClinVar: likely benign; called by muse, varscan2
- CHL1 | c.2415A>T p.G805= (on ENST00000397491 / NM_001253387.1; = p.G821= on NM_006614.4) | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV56601484; called by muse, mutect2
- CLSTN1 | c.2892G>A p.Q964= (on ENST00000377298 / NM_001009566.3; = p.Q954= on NM_014944.4) | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV63130753; called by muse, mutect2, varscan2
- COL28A1 | c.33G>C p.L11= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV68083801; called by muse, mutect2, varscan2
- CWC25 | c.96T>G p.A32= | Silent (SNP) | VAF 20/400 reads (5%) | called by muse, mutect2
- DNAI4 | c.1587A>G p.P529= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV64023100; called by muse, mutect2, varscan2
- DOCK4 | c.5349G>T p.G1783= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV101447929; called by muse, mutect2, varscan2
- DYNC2H1 | c.12426A>G p.R4142= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs1474413723, COSV62102468; called by muse, mutect2
- EAF2 | c.18A>C p.G6= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV56545559; called by muse, mutect2, varscan2
- EPN3 | c.1302C>A p.T434= | Silent (SNP) | VAF 56/215 reads (26%) | catalogued as COSV52142191; called by muse, mutect2, varscan2
- FLG | c.4633A>C p.R1545= | Silent (SNP) | VAF 86/667 reads (13%) | catalogued as rs1204145604, COSV64245923; called by muse, mutect2, varscan2
- FTL | c.168C>G p.A56= | Silent (SNP) | VAF 80/117 reads (68%) | catalogued as rs1472761218, COSV53171355; called by muse, mutect2, varscan2
- GBA | c.939C>T p.H313= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV59170642; called by muse, mutect2
- GRM1 | c.291C>A p.P97= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV51234910; called by muse, mutect2, varscan2
- ITK | c.153G>A p.L51= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV70063430; called by muse, mutect2
- KIAA0100 | c.3081G>A p.R1027= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs758613997, COSV66495521; called by muse, mutect2, varscan2
- KLHDC3 | c.1035C>T p.A345= | Silent (SNP) | VAF 47/402 reads (12%) | catalogued as rs754086366, COSV55065388; called by muse, mutect2, varscan2
- KRT71 | c.633C>T p.D211= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as rs113716134; called by muse, mutect2, varscan2
- LRP1 | c.13272C>T p.I4424= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV54520638; called by muse, mutect2, varscan2
- MYO16 | c.5019C>T p.D1673= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV62758030; called by muse, mutect2, varscan2
- MYOM3 | c.1479T>A p.A493= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV58398363; called by muse, mutect2, varscan2
- OR2L2 | c.861C>T p.I287= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as COSV63558327; called by muse, mutect2, varscan2
- OR4K2 | c.51C>T p.L17= | Silent (SNP) | VAF 44/226 reads (19%) | catalogued as COSV100064807, COSV53850923; called by muse, mutect2, varscan2
- PCDH17 | c.3214T>C p.L1072= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as rs1320589035, COSV64971461, COSV64971783, COSV64972529; called by muse, mutect2, varscan2
- PGAP1 | c.1050T>C p.V350= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV61328437; called by muse, mutect2, varscan2
- PLEKHA6 | c.2895C>T p.N965= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs139252016; called by muse, mutect2, varscan2
- POTEA | c.924A>G p.T308= (on ENST00000519951 / NM_001005365.2; = p.T262= on NM_001002920.1) | Silent (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- PPP1R32 | c.1125C>T p.Y375= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as rs775123503, COSV58544810; called by muse, mutect2, varscan2
- PRPF8 | c.4959C>T p.D1653= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV59266372; called by muse, mutect2, varscan2
- PTCH1 | c.237G>A p.L79= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs547602299, COSV100109320, COSV59487404; ClinVar: likely benign; called by muse, mutect2, varscan2
- RNASEL | c.670C>T p.L224= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as COSV62377608; called by muse, mutect2, varscan2
- RYR2 | c.4296C>A p.I1432= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as COSV63704108; called by muse, mutect2, varscan2
- SI | c.3540T>G p.T1180= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs759754319, COSV52293061, COSV52298252; called by muse, mutect2
- SLC35C2 | c.429G>C p.V143= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV54757986; called by muse, mutect2, varscan2
- SLTM | c.642A>G p.S214= | Silent (SNP) | VAF 60/81 reads (74%) | catalogued as COSV51056486; called by muse, mutect2, varscan2
- SNRPA | c.105C>T p.S35= | Silent (SNP) | VAF 71/93 reads (76%) | catalogued as COSV54682265; called by muse, mutect2, varscan2
- SPDYC | c.711C>T p.C237= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV65865540; called by muse, mutect2, varscan2
- SYNE1 | c.1257C>T p.Y419= (on ENST00000367255 / NM_182961.4; = p.Y426= on NM_033071.3) | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs1479058078, COSV55059965; called by muse, mutect2, varscan2
- SYNRG | c.399C>T p.L133= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as rs537168614; called by muse, mutect2
- TEK | c.2178T>C p.S726= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV66231633; called by muse, mutect2, varscan2
- TMPRSS11B | c.1048T>C p.L350= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV60293539; called by muse, mutect2, varscan2
- TRAV8-2 | c.9G>A p.L3= | Silent (SNP) | VAF 33/97 reads (34%) | called by muse, mutect2, varscan2
- TTN | c.96015C>G p.V32005= (on ENST00000591111; = p.V24581= on NM_003319.4) | Silent (SNP) | VAF 66/158 reads (42%) | catalogued as COSV60245425; called by muse, mutect2, varscan2
- VIL1 | c.1389C>T p.A463= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as rs139447471; called by muse, mutect2, varscan2
- YARS2 | c.195C>T p.F65= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as COSV61402385; called by muse, mutect2, varscan2
- ZFPM2 | c.321G>A p.Q107= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs761645875, COSV68289461; called by muse, mutect2
- ZKSCAN7 | c.552T>A p.P184= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV56273916, COSV99837399; called by muse, mutect2, varscan2
- ZNF320 | c.1158A>T p.T386= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV67087782, COSV67088671; called by muse, mutect2, varscan2
- ZNF549 | c.393T>G p.P131= (on ENST00000376233 / NM_001199295.2; = p.P118= on NM_153263.2) | Silent (SNP) | VAF 83/120 reads (69%) | catalogued as COSV53726096, COSV53727068; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826305 A>T | 3'Flank (SNP) | VAF 17/119 reads (14%) | catalogued as rs770341302; called by muse, mutect2, varscan2
- CSTF2 | c.-2C>T | 5'UTR (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100802959; called by muse, mutect2
- DENND10P1 | n.878G>A | RNA (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- FBXL21P | n.975-424A>G | Intron (SNP) | VAF 9/39 reads (23%) | catalogued as COSV51809777; called by muse, mutect2, varscan2
- FRMPD2B | n.813C>T | RNA (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- MIR509-2 | n.91C>T | RNA (SNP) | VAF 83/164 reads (51%) | catalogued as rs782626709; called by muse, mutect2, varscan2
- SLC30A2 | c.271+603C>T | Intron (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100958607, COSV100958622; called by muse, mutect2
- SSPOP | n.2145C>T | RNA (SNP) | VAF 7/16 reads (44%) | catalogued as rs766051768, COSV50488798; called by muse, mutect2, varscan2
- STAG3L4 | n.387G>T | RNA (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- SUCO | chr1:172532483 T>A | 5'Flank (SNP) | VAF 6/52 reads (12%) | catalogued as COSV55270322, COSV99742904, COSV99744253; called by muse, mutect2, varscan2
